CCDI case PBCVTZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/8d944d9d-d70c-4f1c-bd59-0ff5da01e8d2

Demographics
Sex at birth: female.

Biospecimens (3 samples)
- Sample 0E1HEN: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0E1HF1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0E1HFX: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
